Somatic mutation profile of tumor specimen 0DGJ85 from CCDI case PBBRPL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 14.9 years (5,438 days).
Specimen 0DGJ85: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12d367cd-2c37-4623-b930-2fac33a65836.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGJ62 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05cb7945-348c-4a94-9806-a9536a85b36f

The open-access MAF lists 65 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, Intron 6, 3'UTR 5, Frame Shift Del 3, In Frame Del 3, 5'UTR 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 196/333 reads (59%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, mutect2, varscan2
- ADAR | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 219/704 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1338472867; called by muse, mutect2, varscan2
- ALDH2 | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 137/351 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779006912; called by muse, mutect2, varscan2
- ASB12 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 199/407 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs766798175; called by muse, mutect2, varscan2
- ATRX | c.6761A>G p.H2254R | Missense Mutation (SNP) | VAF 326/627 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM092484, COSV64874045; called by muse, mutect2, varscan2
- CCDC85A | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 124/338 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.944); catalogued as rs767454240, COSV68153358; called by muse, mutect2, varscan2
- CD163L1 | c.3940C>T p.R1314W | Missense Mutation (SNP) | VAF 87/325 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs372730324, COSV58026616; called by muse, mutect2, varscan2
- CLEC4F | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 195/390 reads (50%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.427); catalogued as COSV99713985; called by muse, varscan2
- DKC1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 269/625 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV101059904; called by muse, mutect2, varscan2
- DRC1 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs374438636, COSV104386966; called by muse, mutect2
- ERCC6L2 | c.1954C>T p.H652Y | Missense Mutation (SNP) | VAF 130/436 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs764611661, COSV56628131; called by muse, mutect2, varscan2
- GALNT14 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 170/346 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs377585928; called by muse, mutect2, varscan2
- MAGEE1 | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 27/348 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.497); catalogued as COSV63909815; called by muse, mutect2
- MAGI2 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 336/682 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374007527; called by muse, varscan2
- MCF2L2 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 142/574 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs772064474, COSV100194178; called by muse, mutect2, varscan2
- NR1D1 | c.1300_1302del p.E434del | In Frame Del (DEL) | VAF 152/447 reads (34%) | catalogued as rs746857301; called by mutect2, pindel, varscan2
- PPP2R2B | c.1154G>A p.R385Q (on ENST00000394409; = p.R451Q on NM_181674.2) | Missense Mutation (SNP) | VAF 133/491 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as rs772255940, COSV60762304; called by muse, mutect2, varscan2
- SLIT3 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 167/366 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs556933554, COSV60626730, COSV60637298; called by muse, mutect2, varscan2
- TP53 | c.365_366del p.V122Dfs*26 | Frame Shift Del (DEL) | VAF 268/410 reads (65%) | catalogued as rs587780067; called by pindel, varscan2
- ZNF267 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as rs909059556, COSV56250553; called by muse, mutect2, varscan2
- ACE2 | c.186+2T>A p.X62_splice | Splice Site (SNP) | VAF 156/165 reads (95%) | called by mutect2, varscan2
- ADD2 | c.1994G>C p.G665A | Missense Mutation (SNP) | VAF 152/373 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ANAPC4 | c.1649A>T p.Q550L | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ARMCX5 | c.1240C>A p.L414M | Missense Mutation (SNP) | VAF 79/374 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CAMSAP3 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 119/223 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DCAF12L1 | c.1381C>T p.L461F | Missense Mutation (SNP) | VAF 250/504 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DLC1 | c.91T>A p.C31S | Missense Mutation (SNP) | VAF 259/572 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DOCK11 | c.3089T>C p.F1030S | Missense Mutation (SNP) | VAF 238/464 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNAP | c.372_374del p.I124del (on ENST00000321600; = p.I98del on NM_173629.3) | In Frame Del (DEL) | VAF 171/407 reads (42%) | called by mutect2, pindel, varscan2
- HCFC1 | c.769C>A p.L257I | Missense Mutation (SNP) | VAF 216/401 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IRF6 | c.99_100del p.K34Tfs*13 | Frame Shift Del (DEL) | VAF 228/769 reads (30%) | called by mutect2, pindel, varscan2
- LRRC4C | c.1079C>G p.P360R | Missense Mutation (SNP) | VAF 89/554 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MPPED1 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 16/566 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- MTMR7 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 165/383 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MUC17 | c.4568C>A p.T1523N | Missense Mutation (SNP) | VAF 363/862 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- PCDH15 | c.2635A>G p.S879G | Missense Mutation (SNP) | VAF 117/230 reads (51%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- PDGFRA | c.1161_1163del p.E387del | In Frame Del (DEL) | VAF 208/354 reads (59%) | called by pindel, varscan2
- RAB3C | c.211A>T p.T71S | Missense Mutation (SNP) | VAF 147/344 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- SLIT2 | c.916C>A p.R306S | Missense Mutation (SNP) | VAF 107/196 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- UBE2D3 | c.121-10_121-6del | Splice Region (DEL) | VAF 32/146 reads (22%) | called by pindel, varscan2
- ZBTB47 | c.1362_1363del p.M455Efs*52 | Frame Shift Del (DEL) | VAF 212/570 reads (37%) | called by pindel, varscan2
- AMY2A | c.441T>C p.S147= | Silent (SNP) | VAF 164/574 reads (29%) | catalogued as rs919975792; called by muse, varscan2
- CTNND2 | c.1200C>T p.S400= | Silent (SNP) | VAF 151/367 reads (41%) | called by muse, mutect2, varscan2
- DOT1L | c.876C>T p.R292= | Silent (SNP) | VAF 336/708 reads (47%) | catalogued as rs761132359; called by muse, mutect2
- ETNK2 | c.900G>A p.P300= | Silent (SNP) | VAF 211/600 reads (35%) | catalogued as rs372782006; called by muse, mutect2, varscan2
- MAB21L2 | c.495C>G p.R165= | Silent (SNP) | VAF 195/210 reads (93%) | called by muse, mutect2, varscan2
- MEGF6 | c.4578C>T p.P1526= | Silent (SNP) | VAF 137/411 reads (33%) | catalogued as rs762723979; called by muse, mutect2, varscan2
- MSN | c.75C>T p.T25= | Silent (SNP) | VAF 163/346 reads (47%) | catalogued as rs368380881; called by muse, mutect2, varscan2
- MTMR7 | c.756T>C p.A252= | Silent (SNP) | VAF 164/379 reads (43%) | called by muse, mutect2, varscan2
- QRICH2 | c.3603C>A p.T1201= | Silent (SNP) | VAF 24/586 reads (4%) | catalogued as COSV53155659; called by muse, mutect2
- SPEG | c.5058C>T p.A1686= | Silent (SNP) | VAF 172/397 reads (43%) | called by muse, mutect2, varscan2
- WDR26 | c.345C>T p.G115= (on ENST00000414423 / NM_001379403.1; = p.G15= on NM_025160.7) | Silent (SNP) | VAF 48/688 reads (7%) | called by muse, mutect2
- ADAMTS3 | c.*36A>T | 3'UTR (SNP) | VAF 39/101 reads (39%) | called by muse, mutect2, varscan2
- AFM | c.1059-53G>T | Intron (SNP) | VAF 17/45 reads (38%) | called by mutect2, varscan2
- ASB17 | c.*73C>T | 3'UTR (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- DDC | c.944+2408_944+2410del | Intron (DEL) | VAF 154/373 reads (41%) | catalogued as rs766299524; called by mutect2, pindel, varscan2
- DNAH2 | c.1904+127G>A | Intron (SNP) | VAF 241/549 reads (44%) | catalogued as rs777103431; called by muse, mutect2, varscan2
- FAM219B | c.*83G>C | 3'UTR (SNP) | VAF 12/80 reads (15%) | called by muse, varscan2
- GTF2H3 | c.427+94G>A | Intron (SNP) | VAF 45/100 reads (45%) | called by muse, mutect2, varscan2
- NCR1 | c.*85C>T | 3'UTR (SNP) | VAF 41/88 reads (47%) | catalogued as rs561654531; called by muse, mutect2, varscan2
- SOX4 | c.-512_-511del | 5'UTR (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- SP100 | c.-57C>T | 5'UTR (SNP) | VAF 89/134 reads (66%) | catalogued as rs1422035840; called by muse, mutect2, varscan2
- SPG11 | c.3893-97G>A | Intron (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- SUPT6H | c.*47C>T | 3'UTR (SNP) | VAF 102/190 reads (54%) | called by muse, mutect2, varscan2
- TNFRSF25 | c.744+84G>A | Intron (SNP) | VAF 88/144 reads (61%) | catalogued as rs1258353983, COSV61068623; called by muse, mutect2, varscan2
